Somatic mutation profile of tumor specimen C3N-01825-03 (aliquot CPT0097730006) from CPTAC case C3N-01825, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 70.3 years (25,659 days).
Specimen C3N-01825-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 734ceddb-c52a-40c4-b6f9-64283230f320.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01825-31 (Blood Derived Normal), aliquot CPT0097750002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb44d2cc-c6b7-48b4-87a2-505402dc5adb

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Intron 2, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF3 | c.86A>G p.K29R | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs888496331; called by muse, mutect2
- ERBB3 | c.3019C>T p.P1007S | Missense Mutation (SNP) | VAF 24/442 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs750884386; called by muse, mutect2
- FBXW7 | c.1508C>T p.A503V (on ENST00000281708 / NM_001349798.2; = p.A423V on NM_018315.5) | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV55899659; called by muse, mutect2
- NFASC | c.1002G>T p.K334N (on ENST00000339876 / NM_001378329.1; = p.K345N on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100363436; called by muse, mutect2
- STUB1 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs1235455048; called by muse, mutect2
- STUM | c.339G>T p.W113C | Missense Mutation (SNP) | VAF 16/261 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64684807; called by muse, mutect2
- TBL3 | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1172110224, COSV100225089; called by muse, mutect2
- WDFY4 | c.3698G>T p.R1233L | Missense Mutation (SNP) | VAF 18/287 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100301932; called by muse, mutect2
- ABTB2 | c.1598G>A p.G533E | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CAPN14 | c.1645+2T>G p.X549_splice | Splice Site (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- FCHO1 | c.2434G>A p.E812K | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2
- LRBA | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); called by muse, mutect2
- PCDH10 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 10/270 reads (4%) | called by muse, mutect2
- SOX11 | c.195del p.K66Rfs*25 | Frame Shift Del (DEL) | VAF 12/153 reads (8%) | called by mutect2, pindel
- TGFB3 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 23/386 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.593); called by muse, mutect2
- DIS3L | c.60G>A p.R20= | Silent (SNP) | VAF 9/176 reads (5%) | catalogued as rs1451600081; called by muse, mutect2
- G6PD | c.186C>T p.P62= | Silent (SNP) | VAF 17/253 reads (7%) | catalogued as rs781875587; called by muse, mutect2
- PKD2 | c.720C>T p.G240= | Silent (SNP) | VAF 32/386 reads (8%) | called by muse, mutect2
- SLC10A2 | c.708G>A p.A236= | Silent (SNP) | VAF 16/283 reads (6%) | catalogued as rs1041398293, COSV55360173; called by muse, mutect2
- INPPL1 | c.3686+12G>T | Intron (SNP) | VAF 10/80 reads (13%) | catalogued as rs760040242; called by muse, mutect2
- ITPK1 | c.*3009G>C | 3'UTR (SNP) | VAF 20/155 reads (13%) | called by muse, mutect2, varscan2
- SLC25A14 | c.594+372C>T | Intron (SNP) | VAF 12/205 reads (6%) | called by muse, mutect2
